TCGA case TCGA-97-8547 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac0d7a82-82cb-4aec-b859-e37375f3de8b

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 78.9 years (28,801 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 47 days; Days to treatment end: 111 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 124 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 148 days; Disease response: Tumor Free.
- Days to follow up: 657 days (1.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- EGFR deletion: Positive; Exon: 19.
- KRAS mutation, nos: Negative.

Other clinical attributes
- DLCO (% of predicted): 87; FEV1 before bronchodilator (% of reference): 136.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-8547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 1.2; Shortest dimension: 0.5.
  Slide TCGA-97-8547-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-97-8547-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; EGFR mutation identified type: Exon 19 Deletion; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Pharmaceutical therapy drug name: Tarceva.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 657 days; disease-specific survival: no event (censored), 657 days; disease-free interval: no event (censored), 657 days; progression-free interval: no event (censored), 657 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-8547-01A-11D-2389-01): tumor purity 0.48, ploidy 1.88, whole-genome doublings 0.
